Somatic mutation profile of tumor specimen MP2PRT-PAURDP-TMP1-A (aliquot MP2PRT-PAURDP-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAURDP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 8.4 years (3,074 days).
Specimen MP2PRT-PAURDP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f2111ed-dec2-489e-b52c-e53ec0aea198.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAURDP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAURDP-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ed63914-0748-4643-bc12-d713ddaecf75

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGF2BP1 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1567828704; called by muse, mutect2
- OSBPL5 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 186/416 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377626825; called by muse, mutect2, varscan2
- PCYT2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 217/513 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs896404022; called by muse, mutect2, varscan2
- PKD1 | c.7409C>T p.P2470L | Missense Mutation (SNP) | VAF 121/673 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs539143745; called by muse, mutect2, varscan2
- RAB3C | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 206/396 reads (52%) | SIFT tolerated (1); PolyPhen possibly damaging (0.471); catalogued as rs190927640; called by muse, mutect2, varscan2
- SP1 | c.116G>A p.R39Q (on ENST00000327443 / NM_138473.3; = p.R32Q on NM_003109.1) | Missense Mutation (SNP) | VAF 188/392 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.238); catalogued as rs1251280995; called by muse, mutect2, varscan2
- SPTBN4 | c.4636G>A p.G1546S | Missense Mutation (SNP) | VAF 182/396 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as rs1400801182, COSV100151580; called by muse, mutect2, varscan2
- ZNF100 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 167/341 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as rs764040283; called by muse, mutect2, varscan2
- ACACA | c.3733C>A p.H1245N | Missense Mutation (SNP) | VAF 166/392 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATRX | c.4347del p.E1450Kfs*40 | Frame Shift Del (DEL) | VAF 202/351 reads (58%) | called by pindel, varscan2
- BRD1 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 25/583 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- KLHL25 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 214/440 reads (49%) | called by muse, mutect2, varscan2
- PITX1 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 18/614 reads (3%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- SMC3 | c.2225T>C p.L742P | Missense Mutation (SNP) | VAF 11/316 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- TTC34 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 329/727 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- ZMIZ1 | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 55/537 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACACB | c.5163G>A p.P1721= | Silent (SNP) | VAF 143/307 reads (47%) | catalogued as rs369014502, COSV58133845, COSV58145445; called by muse, mutect2, varscan2
- RPS6KB2 | c.672C>T p.A224= | Silent (SNP) | VAF 41/416 reads (10%) | catalogued as rs751492637, COSV57047778; called by muse, mutect2
- SLC24A1 | c.870C>T p.N290= | Silent (SNP) | VAF 101/564 reads (18%) | catalogued as rs773726222; called by muse, mutect2, varscan2
